Gene-level copy-number profile of tumor specimen HCM-CSHL-0461-D12-86A from HCMI case HCM-CSHL-0461-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Serrated adenoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 54.7 years (19,976 days).
Specimen HCM-CSHL-0461-D12-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6df04114-17f2-44f0-89ec-04de441a1af5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0461-D12-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/12299cd2-162b-4e89-b52f-23e869a70479

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,238; copy number 2: 54,847; copy number 3: 833.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 384. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
